Surgical pathology report (de-identified scan), TCGA case TCGA-05-4425, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4425-01A (Primary Tumor).

Main diagnosis/diagnoses:

Peripheral bronchopulmonary, histologically mixed adenocarcinoma of the middle with pleural invasion and a second small focus or satellite nodule of a tubular adenocarcinoma with a small bronchioalveolar growth component and likewise pleural infiltration (sample 2.)). TNM classification on the basis of this material pT2 pN0 pM1 (PUL) V1 RX, stage IV. C34.2 M8255/3.

Comment/supplementary remark:

The tumor classification as adenocarcinoma of the lung showing a predominantly tubulopapillary structural pattern still requires confirmation by appropriate immunohistochemical analysis. The classification of the second small tumor focus as a (hematogenous) metastasis that – despite a certain difference in histoarchitecture and cell morphology in places – is based on the structure of the focus, which is lacking the fibrous remodeling or cicatricial zone here that is characteristic of a primary peripheral bronchopulmonary carcinoma. Vascular invasion can be seen in the intratumoral, thick-walled pulmonary vessels of the larger tumor, where there is tumor spread with endobronchial occlusion in a subsegmental branch of the bronchus. The R1 classification is explained by the observation that the tumor glands invading the pleura extend as far as the outer surface of the pleura in places and the tumor cells thus remain in the pleural space.

Result of immunohistochemical analysis (both tumor foci)

CK7 positive throughout, CK20 negative. TTF1.positive (in the smaller focus more than in the larger one), only isolated tumor cells with delicate cell membrane staining for surfactant protein B.

This not only confirms that it is an adenocarcinoma of the lung and, but also supports the view that the smaller focus represents the metastasis of the larger focus seen in 1.) and classified as primary tumor.

Source: NCI Genomic Data Commons file dddf7b42-8077-4508-8047-555e2d27299a (TCGA-05-4425.ADAFA26D-044F-4B01-804A-5066EE20CEB6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).